Somatic mutation profile of tumor specimen ALCH-AEUV-TTP1-A (aliquot ALCH-AEUV-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEUV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,539 days).
Specimen ALCH-AEUV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c08c1e1d-0251-4137-84a8-3ec9da9541e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUV-NB1-A (Blood Derived Normal), aliquot ALCH-AEUV-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bd27f1a-0b70-4023-9d05-cf1e915fb087

The open-access MAF lists 212 somatic variants for this specimen: 142 protein-altering or splice-affecting, 36 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 36, Intron 17, Nonsense Mutation 14, RNA 8, 3'UTR 6, Splice Region 3, 5'UTR 2, Translation Start Site 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4223G>A p.W1408* (on ENST00000303395 / NM_001202435.3; = p.W1397* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/266 reads (10%) | catalogued as rs794726784, CM032370; ClinVar: pathogenic; called by muse, mutect2
- AC013489.1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs912398551, COSV51551210, COSV51554431; called by muse, varscan2
- ADGB | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1054374155, COSV62229569; called by muse, mutect2
- AL358113.1 | c.3887G>T p.R1296L | Missense Mutation (SNP) | VAF 36/507 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs370985421, COSV61957484; called by muse, mutect2
- ARNT2 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57586821; called by muse, mutect2, varscan2
- ASXL3 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV52471274; called by muse, mutect2
- ATP11B | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV60032634; called by muse, mutect2
- BCL9L | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as rs1311775225; called by muse, mutect2, varscan2
- C3 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV55567931; called by muse, mutect2
- CDK5 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs1285531773; called by muse, mutect2
- CEMIP | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs761161256, COSV54996171; called by muse, mutect2
- COPA | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54105097; called by muse, mutect2
- CPS1 | c.4475G>T p.R1492M | Missense Mutation (SNP) | VAF 71/619 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99242873; called by muse, mutect2, varscan2
- CST11 | c.113T>C p.M38T | Missense Mutation (SNP) | VAF 54/660 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100776864; called by muse, mutect2
- CTTN | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1327340415, COSV57232041; called by muse, mutect2, varscan2
- CTTNBP2 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1195879443; called by muse, mutect2, varscan2
- DNAH5 | c.9184A>G p.R3062G | Missense Mutation (SNP) | VAF 107/532 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1044335313; called by muse, mutect2, varscan2
- DOC2B | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1274430339; called by muse, mutect2, varscan2
- EFCAB1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 46/568 reads (8%) | catalogued as rs201706002, COSV100030541, COSV50617834; called by muse, mutect2
- EPB41L2 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774883134; called by muse, mutect2
- EYS | c.3304A>T p.T1102S | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1476692282; called by muse, mutect2
- FLG | c.10274C>G p.S3425* | Nonsense Mutation (SNP) | VAF 35/615 reads (6%) | catalogued as COSV64248695; called by muse, mutect2
- FRMD1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 28/296 reads (9%) | catalogued as rs370055309, COSV51961546; called by muse, mutect2
- GABRA2 | c.536C>A p.S179* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | catalogued as COSV62914309, COSV62919289; called by muse, mutect2
- GALNT13 | c.574C>G p.R192G | Missense Mutation (SNP) | VAF 58/657 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67219173; called by muse, mutect2
- H1-4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as COSV56800756; called by muse, mutect2
- HECW2 | c.2465G>T p.R822M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99038590; called by muse, mutect2
- JAG2 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as rs762540989, COSV59307500; called by muse, mutect2, varscan2
- KCNJ3 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54534252; called by muse, mutect2
- KDM1A | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100752553, COSV63086434; called by muse, mutect2
- KIAA0586 | c.824C>G p.S275C (on ENST00000619416 / NM_001244190.2; = p.S290C on NM_014749.5) | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs186378072; called by muse, mutect2
- KIF14 | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186991634; called by muse, mutect2, varscan2
- KIF7 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs370083276; called by muse, mutect2, varscan2
- KLHL1 | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as rs1326704007; called by muse, mutect2
- LRMDA | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 44/628 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs567691214, COSV100994464; called by muse, mutect2
- LRP5 | c.4168G>A p.V1390I | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as rs745582449, COSV99591940; ClinVar: uncertain significance; called by muse, mutect2
- MAGEC1 | c.2747C>A p.A916E | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV53578740; called by muse, mutect2
- MROH2B | c.3836G>A p.R1279Q | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs896692806, COSV68180806; called by muse, mutect2
- NECTIN3 | c.1041A>C p.R347S | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV60552940; called by muse, mutect2
- OR12D2 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 49/559 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101011264; called by muse, mutect2
- OR5T1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs1416070734, COSV57301806; called by muse, mutect2
- PCDH15 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 54/677 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57392166; called by muse, mutect2
- PHF20 | c.291G>C p.W97C | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59189422; called by muse, mutect2
- PRUNE2 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65049316; called by muse, mutect2
- RBMS3 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56165851; called by muse, mutect2, varscan2
- RFX5 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 35/330 reads (11%) | catalogued as COSV51839929; called by muse, mutect2, varscan2
- RNASE11 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 31/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60087346; called by muse, mutect2
- RXYLT1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54167763; called by muse, mutect2
- SLC25A38 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM093168, COSV99827798; called by muse, mutect2, varscan2
- SMC5 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747143, COSV63191732; called by muse, mutect2
- SNX19 | c.1758C>G p.F586L | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99772772; called by muse, mutect2
- SUN5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs929302638; called by muse, mutect2, varscan2
- SYNE1 | c.21613G>A p.V7205M (on ENST00000367255 / NM_182961.4; = p.V7134M on NM_033071.3) | Missense Mutation (SNP) | VAF 60/694 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377449974; ClinVar: uncertain significance; called by muse, mutect2
- SYT9 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV59623303; called by muse, mutect2
- TAC4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.814); catalogued as rs749887131; called by muse, mutect2, varscan2
- THSD7B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs764321163, COSV55714470; called by muse, mutect2, varscan2
- VWDE | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV51734540; called by muse, mutect2
- WDR45 | c.880C>T p.Q294* (on ENST00000376372 / NM_001029896.2; = p.Q295* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 11/147 reads (7%) | catalogued as CD161565, COSV59875984; called by muse, mutect2
- ZNF790 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63212800; called by muse, mutect2, varscan2
- ADA2 | c.1440C>G p.I480M (on ENST00000262607; = p.I239M on NM_177405.3) | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADAMTS10 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2
- AKAP13 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, varscan2
- AMPH | c.207C>G p.G69= | Splice Region (SNP) | VAF 36/332 reads (11%) | called by muse, mutect2, varscan2
- AOC1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- ARSF | c.921G>C p.K307N | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BRWD3 | c.2787G>C p.L929F | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CCDC91 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CENPL | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- CES3 | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- COL11A1 | c.3445C>A p.P1149T | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CSMD3 | c.8200C>A p.P2734T | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.6966C>G p.Y2322* (on ENST00000297405 / NM_001363185.1; = p.Y2218* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 29/402 reads (7%) | called by muse, mutect2
- CYBC1 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- CYP26A1 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- DNMBP | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DSEL | c.2314_2338del p.D772Lfs*5 | Frame Shift Del (DEL) | VAF 37/431 reads (9%) | called by mutect2, pindel
- EYS | c.1917C>G p.I639M | Missense Mutation (SNP) | VAF 58/780 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); called by muse, mutect2
- FAM135B | c.2813G>C p.S938T | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRMD8 | c.414+1G>T p.X138_splice | Splice Site (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- GFI1 | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GHR | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPAM | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 39/566 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- GPR1 | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRXCR1 | c.33C>A p.D11E | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- HCST | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, mutect2
- HEATR9 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HERC1 | c.12700G>A p.D4234N | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- IFFO2 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); called by muse, mutect2
- INTS6 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR2 | c.5882G>T p.C1961F | Missense Mutation (SNP) | VAF 56/701 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- JMJD1C | c.6985G>A p.D2329N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNIP1 | c.609A>C p.L203F (on ENST00000411494 / NM_001034837.3; = p.L192F on NM_014592.4) | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2
- KIF6 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.013); called by muse, mutect2
- KMT2D | c.14783_14789del p.P4928Lfs*65 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- LARP7 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LEFTY2 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LILRA5 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); called by muse, mutect2
- LMX1A | c.380G>C p.R127P | Missense Mutation (SNP) | VAF 46/544 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- MC3R | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- MLLT10 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.526); called by muse, mutect2
- MNS1 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MORN1 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSL3 | c.1274T>A p.I425K (on ENST00000312196 / NM_078629.4; = p.I259K on NM_006800.4) | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- MTPAP | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- MZF1 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- NLRP3 | c.1554C>A p.F518L | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- NOS2 | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 36/639 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2
- NPAP1 | c.2664C>G p.S888R | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.503); called by muse, mutect2
- NT5E | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- NYNRIN | c.5075G>T p.S1692I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OR11L1 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 55/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OR1M1 | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2L5 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5T3 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- PCGF3 | c.681+3G>A | Splice Region (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- PIP5K1C | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- PRSS21 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSAT1 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 18/563 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPN14 | c.2678T>C p.M893T | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- REG1B | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- SCUBE2 | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- SFTPA2 | c.397A>C p.T133P | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A6 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- SOD2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); called by muse, mutect2
- SPHKAP | c.1823T>A p.M608K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- SUPT6H | c.2321A>T p.N774I | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by muse, mutect2
- SYNE1 | c.2257G>T p.E753* (on ENST00000367255 / NM_182961.4; = p.E760* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 40/591 reads (7%) | called by muse, mutect2
- TCF4 | c.1823A>T p.H608L | Missense Mutation (SNP) | VAF 53/526 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- TECRL | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2
- TENM1 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.046); called by muse, mutect2
- TGFBRAP1 | c.310A>T p.M104L | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- TRIM49B | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 48/612 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.069); called by muse, mutect2
- TRIML1 | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTC19 | c.678G>T p.V226= | Splice Region (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- TUBA4A | c.1070A>C p.Y357S | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.094); called by muse, mutect2
- UROS | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 56/669 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- VSTM2A | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2
- ZCCHC4 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF407 | c.3919G>T p.E1307* | Nonsense Mutation (SNP) | VAF 25/260 reads (10%) | called by muse, mutect2
- ZNF451 | c.3042G>T p.L1014F (on ENST00000370706 / NM_001031623.3; = p.L966F on NM_015555.2) | Missense Mutation (SNP) | VAF 42/509 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZNF462 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.113); called by muse, mutect2
- ZNF813 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA12 | c.3507C>T p.F1169= (on ENST00000272895 / NM_173076.3; = p.F851= on NM_015657.3) | Silent (SNP) | VAF 35/500 reads (7%) | called by muse, mutect2
- ADRM1 | c.120G>A p.P40= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- AHNAK | c.9075G>C p.V3025= | Silent (SNP) | VAF 18/508 reads (4%) | called by muse, mutect2
- ARHGEF1 | c.2034C>T p.L678= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs1251565969, COSV100528816; called by muse, mutect2
- ASAP1 | c.1651A>C p.R551= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- ATP8A2 | c.3543C>T p.T1181= | Silent (SNP) | VAF 28/280 reads (10%) | called by mutect2, varscan2
- BCL11B | c.1725G>A p.G575= (on ENST00000357195 / NM_001282237.2; = p.G504= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- CCDC166 | c.198G>A p.A66= | Silent (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- CHD6 | c.4255C>T p.L1419= | Silent (SNP) | VAF 49/419 reads (12%) | called by muse, mutect2, varscan2
- CHRNB2 | c.1362C>T p.V454= | Silent (SNP) | VAF 32/554 reads (6%) | catalogued as rs772921552; called by muse, mutect2
- CPQ | c.567G>A p.Q189= | Silent (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- DCC | c.1020G>C p.L340= | Silent (SNP) | VAF 98/715 reads (14%) | called by muse, mutect2, varscan2
- DMGDH | c.396A>G p.P132= | Silent (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- EMSY | c.3609G>A p.Q1203= | Silent (SNP) | VAF 63/332 reads (19%) | called by muse, mutect2, varscan2
- EVI2B | c.699A>G p.L233= | Silent (SNP) | VAF 23/318 reads (7%) | called by muse, mutect2
- ITGA10 | c.2421C>T p.I807= | Silent (SNP) | VAF 35/427 reads (8%) | catalogued as rs1202784206; called by muse, mutect2
- KAT6B | c.976C>T p.L326= | Silent (SNP) | VAF 58/631 reads (9%) | called by muse, mutect2
- KIF5A | c.1971G>A p.L657= | Silent (SNP) | VAF 50/443 reads (11%) | called by muse, mutect2, varscan2
- LRP1B | c.543G>T p.V181= | Silent (SNP) | VAF 22/552 reads (4%) | called by muse, mutect2
- MAP9 | c.108A>T p.S36= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- MCM3AP | c.2379G>C p.L793= | Silent (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- MUC5B | c.14379G>A p.L4793= | Silent (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- NLRP8 | c.1989C>G p.T663= | Silent (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2
- OR2M3 | c.525C>A p.A175= | Silent (SNP) | VAF 50/263 reads (19%) | called by muse, mutect2, varscan2
- OR51I1 | c.189C>T p.Y63= | Silent (SNP) | VAF 40/482 reads (8%) | called by muse, mutect2
- OR52D1 | c.78C>A p.A26= | Silent (SNP) | VAF 21/302 reads (7%) | called by muse, mutect2
- PCDH9 | c.2457C>A p.I819= | Silent (SNP) | VAF 42/476 reads (9%) | called by muse, mutect2
- PCDHB11 | c.2112G>A p.S704= | Silent (SNP) | VAF 28/409 reads (7%) | called by muse, mutect2
- PMP22 | c.240G>A p.L80= | Silent (SNP) | VAF 60/603 reads (10%) | called by muse, mutect2
- PPFIA3 | c.2355C>T p.D785= | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- SH3BGRL3 | c.99C>T p.I33= | Silent (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- TEK | c.2652C>T p.N884= | Silent (SNP) | VAF 71/692 reads (10%) | catalogued as rs1429711144; called by muse, mutect2, varscan2
- TRIM51 | c.699G>C p.L233= | Silent (SNP) | VAF 52/588 reads (9%) | called by muse, mutect2
- USH2A | c.7539C>A p.S2513= | Silent (SNP) | VAF 79/435 reads (18%) | catalogued as COSV56351587; called by muse, mutect2, varscan2
- WSB2 | c.886C>T p.L296= | Silent (SNP) | VAF 36/437 reads (8%) | catalogued as COSV99969991; called by muse, mutect2
- XRN2 | c.2736A>T p.L912= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- ABCC8 | c.1333-37C>T | Intron (SNP) | VAF 29/340 reads (9%) | catalogued as rs1010686404; called by muse, mutect2
- AL353804.4 | chrX:73824006 T>C | 5'Flank (SNP) | VAF 18/157 reads (11%) | catalogued as rs770147179; called by muse, mutect2, varscan2
- AL359195.2 | n.3347C>A | RNA (SNP) | VAF 31/316 reads (10%) | catalogued as rs541867816; called by muse, mutect2
- C5orf17 | n.379G>A | RNA (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- CACNB2 | c.214-60987G>C | Intron (SNP) | VAF 16/470 reads (3%) | called by muse, mutect2
- CLCNKB | c.*292G>C | 3'UTR (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- COL11A1 | c.898-199A>G | Intron (SNP) | VAF 52/706 reads (7%) | catalogued as rs1324692916, COSV62202149; called by muse, mutect2
- COLEC11 | c.328+993G>A | Intron (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- DHX40 | c.1806+28A>G | Intron (SNP) | VAF 27/313 reads (9%) | catalogued as rs765786197; called by muse, mutect2
- DPPA4 | c.679+65C>T | Intron (SNP) | VAF 25/272 reads (9%) | catalogued as rs762777999; called by muse, mutect2
- EIF4G3 | c.-126G>T | 5'UTR (SNP) | VAF 40/341 reads (12%) | called by muse, mutect2, varscan2
- FAM120C | c.699+8371A>T | Intron (SNP) | VAF 31/333 reads (9%) | called by muse, mutect2
- FSD1L | c.1026-3948G>C | Intron (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- GRIP1 | c.*28G>C | 3'UTR (SNP) | VAF 21/283 reads (7%) | called by muse, mutect2
- HCN1 | c.-28G>A | 5'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- HGF | c.482+1133G>T | Intron (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- HSPA7 | n.745C>T | RNA (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- IGSF9B | c.64+4677C>T | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- IMMT | c.1032+89C>T | Intron (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- IMPG2 | c.*55G>T | 3'UTR (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
- ITGB1 | c.2331+1296C>G | Intron (SNP) | VAF 38/478 reads (8%) | called by muse, mutect2
- LINC00602 | n.93C>A | RNA (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- MCF2L | c.*136G>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as rs1566895211; called by muse, mutect2, varscan2
- MIR337 | n.1G>A | RNA (SNP) | VAF 14/122 reads (11%) | catalogued as rs1233030515; called by muse, mutect2
- MTUS2 | c.3118-11115A>G | Intron (SNP) | VAF 24/278 reads (9%) | catalogued as rs373524065, COSV66421275; called by muse, mutect2
- NBPF22P | n.945G>T | RNA (SNP) | VAF 20/277 reads (7%) | called by muse, mutect2
- OR2W5 | n.479C>A | RNA (SNP) | VAF 88/676 reads (13%) | catalogued as rs769292126; called by muse, mutect2, varscan2
- OR8H1 | c.*36C>A | 3'UTR (SNP) | VAF 12/196 reads (6%) | catalogued as rs753365115; called by muse, mutect2
- PEX12 | c.*14C>G | 3'UTR (SNP) | VAF 14/475 reads (3%) | called by muse, mutect2
- SLC22A16 | c.53+1577A>G | Intron (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- SPATA31C2 | n.1341G>A | RNA (SNP) | VAF 60/653 reads (9%) | catalogued as rs765552118; called by muse, mutect2
- TENM4 | c.494-344C>T | Intron (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- TRIM2 | c.-49+51247G>A | Intron (SNP) | VAF 37/308 reads (12%) | called by muse, mutect2, varscan2
- ZFP28 | c.898+101C>T | Intron (SNP) | VAF 35/357 reads (10%) | called by muse, mutect2
